Surgical pathology report (de-identified scan), TCGA case TCGA-M7-A722, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of North Carolina, specimen TCGA-M7-A722-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY

Case Number :

Diagnosis:

A: Lymph nodes, right pelvic, excision
- No tumor seen in two lymph nodes (0/2).

B: Lymph nodes, left pelvic, excision
- No tumor seen in two lymph nodes (0/2).

C: Prostate, robot assisted laparoscopic prostatectomy

Tumor histologic type: prostatic adenocarcinoma

Tumor grade (Gleason system): 8 (4+4), with minor tertiary component of pattern 3 comprising approximately 3% of tumor volume, and minor component of pattern 5 comprising approximately 1% of tumor volume

Approximate percentage of prostate involved by tumor: right lobe 42%; left lobe 2%

Extent of tumor:

Location of tumor involvement in prostate: right lobe apex to mid; left lobe apex to mid

Confinement/non-confinement of tumor within the prostatic capsule: non-confined

Location of extracapsular tumor involvement: right apex (C3), right mid (C6, C7), right base (C10)

Type of extracapsular tissue involved within tumor: fibrovascular and fibroadipose soft tissue (C3, C6, C7, C10)

Lymphovascular space invasion: Hemangiovascular space invasion (venous) identified (C5); negative for definite lymphovascular space invasion

Seminal vesicles (invasion of muscular wall required): negative

Histologic assessment of surgical margins: focally positive; right mid, microscopic focus <0.1 cm (C7), left apex, microscopic focus <0.1 cm (C13)

Other significant findings: extensive perineural invasion identified; high grade prostatic intraepithelial neoplasia; acute prostatitis

ICD-O-3
c66f
Adenocarcinoma,
path acinar 8/40/3
Adenocarcinoma NOS
8/40/3
Site: Prostate NOS
C61.9
JW 8/12/13

[page 2 of 4]
Lymph nodes: separately submitted

Size and location of largest tumor metastasis: not applicable

Extracapsular extension of tumor in lymph nodes: not applicable

AJCC Staging: pT3a pN0

This staging information is based on this pathologic specimen and may be incomplete. A comprehensive review of all available information is recommended to determine final staging.

Comment:

The frozen section diagnoses are confirmed.

Intraoperative Consult Diagnosis:

Frozen section was requested by Dr. from on at

FSA1: Right pelvic lymph nodes, removal

- No tumor seen in two lymph nodes (0/2)

FSB1: Left pelvic lymph nodes, removal

- No tumor seen in two lymph nodes (0/2)

Drs. at

Frozen Section Pathologist:

Clinical History:

The patient is a -year-old man with history of right lobe prostate adenocarcinoma.

Gross Description:

Received are three appropriately labeled containers.

Container A is additionally labeled "right pelvic lymph nodes."

It consists of a 4.5 x 2.5 x 0.7 cm fibrofatty tissue aggregate.

Two lymph node candidates are identified. The first measures 4.5 x 1.2 x 0.6 cm and is submitted in block FSA2-FSA3, bisected.

The second measures 7 x 5 x 3 mm and is entirely submitted in block FSA1, bisected.

Container B is additionally labeled "left pelvic lymph nodes."

It consists of a 4 x 3.5 x 0.7 cm fibrofatty tissue aggregate

[page 3 of 4]
with two lymph node candidates. The first measures 4.0 x 1.2 x 0.5 cm and is submitted entirely in block FSB2-FSB3, bisected. The second measures 1.6 x 0.5 x 0.3 cm and is entirely submitted in block FSB1, bisected.

Container C:

Specimen fixation: formalin

Type of specimen(s) received: robot assisted laparoscopic prostatectomy

Size of specimen: 4.4 cm medial to lateral, 3.5 cm superior to inferior, 3.8 cm anterior to posterior

Weight of specimen: 34.8 grams

Orientation: Right=blue, left=black, apex=yellow, bladder neck=red

Size and description of other organs or structures: There is 3.0 x 1.4 x 0.8 cm of attached right seminal vesicle, 3.8 x 0.4 cm of attached right vas deferens. There is 2.9 x 1.5 x 0.9 cm of attached left seminal vesicle and 2.8 x 0.4 cm of attached left seminal vesicle.

Gross description of prostate: Sectioning from apex towards base reveals minimal periurethral nodularity. There is a 2.4 x 1.4 x 1.3 cm soft fleshy circumscribed nodule in the right apex along the posterior lobe. This markedly expands the right lobe in this area. The remainder of the prostate is homogeneous, gray/tan on gross examination.

Digital photograph taken: not taken

Tissue given for specimen investigations: Tumor and normal are given to

Block Summary:

(Inking: right=blue, left=black, apex=yellow, bladder neck=red)

C1 - right apex, serially sectioned perpendicular to the inked surgical margin

C2-C10 - right side of prostate, submitted from apex towards base, respectively

C11 - right bladder neck, serially sectioned perpendicular to the inked surgical margin

[page 4 of 4]
C12 - right vas deferens margin of resection and representative section of right seminal vesicle

C13 - left apex, serially sectioned perpendicular to the inked surgical margin

C14-C23 left prostate, submitted from apex towards base, respectively

C24 - left bladder neck, serially sectioned perpendicular to the inked surgical margin

C25 - left vas deferens margin of resection and representative section of left seminal vesicle

A small amount of vas deferens and seminal vesicle tissue remain in formalin. The entire prostate has been submitted for histologic evaluation.

Source: NCI Genomic Data Commons file 37a5cf8f-ce8d-44d1-804a-6adb8f5da0b4 (TCGA-M7-A722.4D0EE4BC-69EC-45D2-8739-24E1FE1A526A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).